CCDI case PBBWNI — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/3ffe3db5-f0c7-4e2e-8179-daf0a9d8da1a

Demographics
Sex at birth: male; Race: white; Vital status: Alive.

Diagnoses (1)
1. Astrocytoma, NOS: ICD-O-3 morphology code: 9400/3; Tissue or organ of origin: Temporal lobe; Age at diagnosis: 0.3 years (94 days).

Biospecimens (2 samples)
- Sample 0DQS02: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DQS0H: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
